Somatic mutation profile of tumor specimen ALCH-ACWO-TTP1-A (aliquot ALCH-ACWO-TTP1-A-1-0-D-A509-36) from ALCHEMIST case ALCH-ACWO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.8 years (26,595 days).
Specimen ALCH-ACWO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41130865-1902-4034-8bce-ed0c63d8ef65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACWO-NB1-A (Blood Derived Normal), aliquot ALCH-ACWO-NB1-A-1-0-D-A509-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2eb0125a-5b98-4a4f-9a75-c03d55beadef

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 10, Nonsense Mutation 5, Intron 2, Splice Region 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 215/781 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs372993151, COSV51439217; called by muse, mutect2, varscan2
- B2M | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV62562854; called by muse, mutect2, varscan2
- FSCB | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as COSV61219326; called by muse, mutect2, varscan2
- MYH9 | c.4903G>T p.E1635* | Nonsense Mutation (SNP) | VAF 76/650 reads (12%) | catalogued as COSV53383317; called by muse, mutect2
- NPY2R | c.494G>C p.S165T | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.794); catalogued as COSV61527491; called by muse, mutect2
- SETD2 | c.6376G>T p.E2126* | Nonsense Mutation (SNP) | VAF 178/470 reads (38%) | catalogued as COSV57457788; called by muse, mutect2, varscan2
- SLC12A1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866416134; called by muse, mutect2, varscan2
- SPEG | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 73/1394 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs376718418; called by muse, mutect2
- SYNE1 | c.17866C>T p.R5956C (on ENST00000367255 / NM_182961.4; = p.R5885C on NM_033071.3) | Missense Mutation (SNP) | VAF 38/564 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs558631055, COSV99556173; ClinVar: uncertain significance; called by muse, mutect2
- DNAH1 | c.8733G>T p.K2911N | Missense Mutation (SNP) | VAF 26/559 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- ERBIN | c.3985G>T p.D1329Y (on ENST00000284037 / NM_001253697.2; = p.D1288Y on NM_018695.4) | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOXL1 | c.969C>A p.Y323* | Nonsense Mutation (SNP) | VAF 146/516 reads (28%) | called by muse, mutect2, varscan2
- OTUD5 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 113/394 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB3 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 90/571 reads (16%) | called by muse, mutect2, varscan2
- PPP4R3C | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RRP12 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 89/477 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- SCN2A | c.3863G>A p.S1288N | Missense Mutation (SNP) | VAF 95/405 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIPA1 | c.1499A>T p.N500I | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STAM | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 126/479 reads (26%) | called by muse, mutect2, varscan2
- TAS2R19 | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZMYM4 | c.3435C>T p.D1145= | Splice Region (SNP) | VAF 62/371 reads (17%) | called by muse, mutect2, varscan2
- ZNF48 | c.223T>A p.W75R | Missense Mutation (SNP) | VAF 108/356 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CPXM1 | c.1419C>T p.A473= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- CRACD | c.1947C>T p.S649= | Silent (SNP) | VAF 33/477 reads (7%) | catalogued as COSV51733375; called by muse, mutect2
- EVC2 | c.3354C>T p.C1118= | Silent (SNP) | VAF 187/712 reads (26%) | called by muse, mutect2, varscan2
- HPSE2 | c.408G>A p.G136= | Silent (SNP) | VAF 222/838 reads (26%) | called by muse, mutect2, varscan2
- NLRP5 | c.1410G>A p.V470= | Silent (SNP) | VAF 27/411 reads (7%) | catalogued as rs1442745016; called by muse, mutect2
- OLFML1 | c.726G>A p.Q242= | Silent (SNP) | VAF 108/439 reads (25%) | called by muse, mutect2, varscan2
- OR56A5 | c.174G>A p.L58= | Silent (SNP) | VAF 62/209 reads (30%) | called by muse, mutect2, varscan2
- TMBIM6 | c.573C>G p.L191= | Silent (SNP) | VAF 56/278 reads (20%) | called by muse, varscan2
- TTBK1 | c.2583C>T p.T861= | Silent (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- VPS13D | c.6096T>C p.V2032= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73846347 A>C | 5'Flank (SNP) | VAF 225/795 reads (28%) | called by muse, mutect2, varscan2
- NINL | c.1810+34A>G | Intron (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- RPS11 | c.224-152G>T | Intron (SNP) | VAF 224/904 reads (25%) | called by muse, mutect2, varscan2
- ZC3H15 | c.*305T>G | 3'UTR (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
